Surgical pathology report (de-identified scan), TCGA case TCGA-06-0141, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0141-01A (Primary Tumor).

[page 1 of 2]
PATHOLOGICAL DIAGNOSIS:

A,B. BRAIN, LEFT OCCIPITAL, EXCISION: GLIOBLASTOMA MULTIFORME.

ADDENDUM DIAGNOSIS: MIB-1 PROLIFERATION INDEX 16%.

SEE MICROSCOPIC AND COMMENT.

Operation/Specimen: UPDATED REPORT - Craniotomy, brain.

Clinical History and Pre-Op Dx: [REDACTED] with left occipital enhancing lesion with central necrosis.

GROSS PATHOLOGY: A. Received fresh, several fragments, 1.5 cm across, in aggregate. Soft, focally hemorrhagic, tannish-brown. In total # 1 and 2.

INTRAOPERATIVE CONSULTATION: Brain, left occipital: High grade glioma (C/W glioblastoma multiforme).

B.
SPECIMEN: Left occipital lesion - permanent.
FIXATIVE: None.
GENERAL: A 2.5 x 2.0 x .6 cm. aggregate of tan-red soft friable brain tissue fragments and blood clot. All submitted.
SECTIONS: 3,4 - smaller fragments; X1 - largest fragment.
[REDACTED]

MICROSCOPIC: A,B. Portions of a glial neoplastic proliferation in which the tumor cells have clear nuclear features of anaplasia. The background is fibrillary, and contains vessels with microvascular cellular proliferation throughout. There are also extensive areas of tumor necrosis with necrosis and thrombosis of vessels. The necrotic tissue focally contains numerous polymorphonuclear neutrophils. There are mitotic figures.

Cont'd...

COMMENT: In both specimens there is a glioblastoma multiforme. There are extensive areas of tumor necrosis, with the presence focally of
[REDACTED]

[page 2 of 2]
[REDACTED]

polymorphonuclear neutrophils.

TCGA-06-0141

ADDENDUM REPORT

SPECIAL STAIN: An immunoperoxidase method for MIB-1 was performed on sections from block #1. A proliferation index of 16% was determined in the more active areas.

[REDACTED]

Source: NCI Genomic Data Commons file 76c6dc9f-0ae2-4186-94a7-92c6b8e93b29 (TCGA-06-0141.CAA0B0EC-7B94-4326-99D5-483FED429ED4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).